Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3313, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3313-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Histopathological Examination

Path#:
Collected:
Received:
Complete:

Pre-Op Diagnosis :
Order Physician :
Specimens : Kidney, Right
Frozen Diagnosis :

Report : GROSS EXAMINATION.

The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a right kidney which measures en bloc 13 x 9.5 x 5.5 cm and weighs 312 g. There is a 3.0 cm segment of ureter attached. Ureter and vascular margins are sampled in block one. The ureter is opened. No tumor within the ureter is grossly identified. The ureteropelvic junction is sampled in block two. The kidney is bivalved. On the anterior aspect of the kidney bulging beneath the capsule is a tan partially cystic mass which measures 4.5 x 4.0 x 3.5 cm. An extension of the mass extends into the renal vein. A cross section of the vein and tumor are submitted in block three. The capsule at the area of tumor is marked with ink and a representative section is submitted in block four. The capsule strips with relative ease. Tumor and adjacent normal appearing kidney tissue are sampled in blocks 5 through 7. Tumor kidney and renal vessel are sampled in block eight. The surface of the kidney exhibit multiple fluid filled cystic structures which measure up to 1.2 cm in greatest dimension and is sampled in block nine. A section of normal appearing kidney is sampled in block 10. The perinephric fat is examined for adrenal tissue. Adrenal gland is not identified. Representative sections are submitted.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy.
LATERALITY: Right.
TUMOR SITE: Middle.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 4.5 x 4 x 3.5 cm.

[page 2 of 2]
MACROSCOPIC EXTENT OF TUMOR: Limited to the kidney.
HISTOLOGIC TYPE: Clear cell renal carcinoma.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Fuhrman nuclear grade III.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1b: Tumor 7 cm or less in deep greatest dimension, limited to the kidney.
REGIONAL LYMPH NODES (PN): pNX.
DISTANT METASTASIS (PM): pMX.
MARGINS: Margins not involved by invasive carcinoma.
ADRENAL GLAND: Not present.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
[T-71000 M-83103 189.0 P3-44070]

CASE SUMMARY:

This 4.5 cm greatest diameter clear cell carcinoma, Fuhrman nuclear grade III is confined to the kidney. The pathologic code pT1bNXMX.

Intradepartmental consultation was obtained.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 82ababc5-ba75-48df-a286-fbcfba1eab46 (TCGA-A3-3313.738DB1A1-3CF3-41E6-A13D-2DC831FEF1A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).